Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VE, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VE-01A (Primary Tumor).

[page 1 of 2]
Neck
d Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Left thyroid FNA = papillary carcinoma.

Specimens Submitted:

1: Total thyroidectomy

DIAGNOSIS:

1. Total thyroidectomy:

Part # 1

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.7 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Mild

Parathyroid Glands:

Not identified

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5212
2D

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid. The right lobe measures 4.3 x 2.8 x 1.6 cm, the left lobe measures 4.3 x 3.3 x 1.7 cm and the isthmus measures 1.8 x 1.4 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.7 x 1.6 x 1.3 cm ovoid, tan-white, friable, encapsulated nodule in the left lower pole. Superior to this is a 0.5 x 0.5 x 0.5 cm ovoid, tan-white, unencapsulated nodule which abuts the anterior aspect. Sections through the remaining tissue reveals red tan, beefy cut surfaces. A portion of the specimen is previously submitted for The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:

LLN - left lobe nodule

LL - left lobe

RL - right lobe

IS - isthmus

Summary of Sections:

Part 1: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
3	LL	4
8	LLN	8
3	RL	4

Source: NCI Genomic Data Commons file ce1d17d7-5b78-4a54-a8e6-48b7faffbaa4 (TCGA-DJ-A3VE.FC2448D9-4FD8-4500-9B0C-293CAC511E17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).